Gene-level copy-number profile of tumor specimen TCGA-NC-A5HN-01A from TCGA case TCGA-NC-A5HN, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.1 years (28,151 days).
Specimen TCGA-NC-A5HN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d17cc543-60a9-46f4-b735-7b9f3960f0cc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NC-A5HN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/be5c982e-d0ad-4f70-a49b-a45987bad073

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,444; copy number 2: 13,015; copy number 3: 26,960; copy number 4: 10,109; copy number 5: 3,313; copy number 6: 3,386; copy number 7: 1,428; copy number 8: 29; copy number 11: 9; copy number 12: 37; copy number 15: 44; copy number 38: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NC-A5HN-01A-11D-A26L-01): tumor purity 0.82, ploidy 3.11, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,967,752–21,995,301, 1 gene: CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,571 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:201,387,858–201,480,846, 1 gene, copy number 8 (within-gene range 6–8): STRADB.
- chr2:201,423,513–201,895,550, 19 genes, copy number 8 (within-gene range 2–8): Y_RNA, C2CD6, MTCO2P16, MTATP6P16, MTCO3P16, MTND3P16, MTND4LP16, MTND4P29, MTND5P31, TMEM237, ENO1P4, AC007279.1, MPP4, RNU6-651P, ALS2, RPS2P16, CDK15, Y_RNA, UBE2V1P11.
- chr3:121,356,991–121,660,927, 9 genes, copy number 11: AC079841.1, AC079841.2, POLQ, RPL7AP11, ARGFX, FBXO40, HCLS1, RN7SL172P, RNU4-62P.
- chr3:134,597,801–135,260,467, 1 gene, copy number 7 (within-gene range 5–7): EPHB1.
- chr3:135,138,469–183,555,706, 735 genes, copy number 7–38 (within-gene range 6–38) (broad region; genes not listed).
- chr5:2,921,496–4,147,429, 10 genes, copy number 7 (within-gene range 5–7): AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063.
- chr7:156,186,122–159,233,377, 49 genes, copy number 7: Y_RNA, AC093813.1, LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr14:92,253,493–106,875,071, 657 genes, copy number 7 (broad region; genes not listed).
- chr16:23,835,983–24,220,611, 1 gene, copy number 8 (within-gene range 2–15): PRKCB.
- chr16:24,098,239–24,572,863, 9 genes, copy number 8–15: AC130448.1, MIR1273H, AC130448.2, LINC02194, CACNG3, AC004125.1, RNU7-24P, AC008938.1, RBBP6.
- chr19:38,844,729–39,435,949, 37 genes, copy number 12: AC008982.2, RINL, AC011455.1, SIRT2, NFKBIB, CCER2, SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17, AC011455.8, FBXO27, AC010605.1, ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16.
- chr20:31,257,664–32,032,180, 43 genes, copy number 15: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L.

Autosomal genes at a single copy (total copy number 1): 679. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
